Gene-level copy-number profile of tumor specimen TCGA-AA-A029-01A from TCGA case TCGA-AA-A029, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 67.6 years (24,686 days).
Specimen TCGA-AA-A029-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.5d641a8b-9e58-4301-8897-f8584728de89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A029-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/670e7a1d-57eb-4695-a15a-4425892dcbaa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 2,432; copy number 2: 41,805; copy number 3: 15,363; copy number 4: 84.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A029-01A-01D-A008-01): tumor purity 0.88, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 120 genes in 56 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,771,296–7,781,432, 2 genes: VAMP3, Z98884.2.
- chr1:36,136,570–36,180,849, 2 genes: TRAPPC3, MAP7D1.
- chr1:46,532,166–46,543,969, 1 gene (within-gene range 0–2): TMEM275.
- chr1:53,459,399–53,467,488, 1 gene: DMRTB1.
- chr1:100,538,139–100,542,021, 1 gene: GPR88.
- chr1:109,483,479–109,509,738, 3 genes: ATXN7L2, CYB561D1, AMIGO1.
- chr1:233,295,325–233,295,727, 1 gene: AL133380.1.
- chr1:241,357,343–241,364,054, 1 gene: AL359764.1.
- chr3:71,675,414–71,786,425, 4 genes (within-gene range 0–2): EIF4E3, GPR27, PROK2, AC096970.1.
- chr3:133,546,071–133,590,261, 3 genes: AC022296.3, AC022296.1, CDV3.
- chr4:76,886,029–76,898,144, 3 genes: AC104687.2, AC104687.1, SOWAHB.
- chr5:76,170,930–76,174,183, 2 genes: AC113404.2, AC113404.3.
- chr5:157,731,420–157,760,709, 3 genes (within-gene range 0–2): THG1L, LSM11, AC026407.1.
- chr7:6,590,021–6,658,279, 3 genes (within-gene range 0–3): C7orf26, ZNF853, ZNF316.
- chr7:149,191,043–149,226,238, 2 genes: AC004890.1, ZNF282.
- chr8:96,140,572–96,160,806, 2 genes: AP003465.2, GDF6.
- chr10:91,153,669–91,161,315, 1 gene (within-gene range 0–2): AL731553.1.
- chr11:6,603,642–6,658,396, 10 genes: AC091564.2, ILK, TAF10, AC091564.3, AC091564.7, TPP1, AC091564.6, DCHS1, AC091564.4, AC091564.5.
- chr11:17,385,859–17,389,331, 1 gene: KCNJ11.
- chr11:44,719,392–44,736,692, 1 gene: TSPAN18-AS1.
- chr11:74,738,478–74,746,114, 2 genes: AP001324.2, AP001324.1.
- chr11:129,295,286–129,296,481, 1 gene: ZNF123P.
- chr11:130,040,365–130,041,071, 1 gene: AP003041.2.
- chr11:130,082,495–130,082,781, 1 gene: RPL34P21.
- chr12:67,648,338–67,665,406, 1 gene (within-gene range 0–3): DYRK2.
- chr12:101,696,002–101,696,450, 1 gene: AC010205.1.
- chr13:113,149,432–113,208,715, 4 genes: AL137002.2, PROZ, AL137002.1, PCID2.
- chr14:56,117,316–56,117,990, 1 gene: AL138995.1.
- chr14:74,614,693–74,616,647, 1 gene: AC013451.2.
- chr14:95,521,943–95,544,724, 3 genes (within-gene range 0–2): SNHG10, SCARNA13, GLRX5.
- chr15:78,250,502–78,282,196, 2 genes (within-gene range 0–2): AC090607.3, DNAJA4.
- chr15:101,495,052–101,495,567, 1 gene: AC090164.2.
- chr16:49,277,917–49,281,838, 1 gene: CBLN1.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr18:78,976,555–79,002,677, 2 genes: LINC01896, SALL3.
- chr20:646,615–675,802, 3 genes: SRXN1, AL121758.1, SCRT2.
- chr20:62,122,461–62,143,440, 2 genes: LSM14B, PSMA7.
- chr21:39,313,935–39,349,647, 4 genes: BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA.
- chr22:17,116,297–17,132,104, 2 genes: TMEM121B, LINC01664.
- chr22:50,529,710–50,801,309, 22 genes: ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 54. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
